Somatic mutation profile of tumor specimen BA2545D (aliquot aq-BA2545D) from BEATAML1.0 case 2488, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Myeloid sarcoma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 37.9 years (13,856 days).
Specimen BA2545D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8a590e3-c74c-4961-97bb-d81842b2df52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2961D (Solid Tissue Normal), aliquot aq-BA2961D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d2c7134-5b91-4cc6-b11a-4498c1b61d04

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEPCE | c.1994C>A p.A665D | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV99439840; called by muse, mutect2
- CEP131 | c.2304G>T p.Q768H (on ENST00000269392 / NM_001319228.2; = p.Q765H on NM_014984.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2
- FBRSL1 | c.2323C>A p.Q775K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- TMEM63B | c.711+112C>A | Intron (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
